Somatic mutation profile of tumor specimen TCGA-WC-A881-01A (aliquot TCGA-WC-A881-01A-12D-A39W-08) from TCGA case TCGA-WC-A881, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.1 years (27,443 days).
Specimen TCGA-WC-A881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2081684-74f4-4955-8338-b445cb777c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A881-10A (Blood Derived Normal), aliquot TCGA-WC-A881-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff7e42c8-85e5-452f-a395-a04fd19841f7

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLEC4M | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50224280; called by muse, mutect2, varscan2
- SLIT2 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1376555171; called by muse, mutect2, varscan2
- TF | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs371174384; called by muse, mutect2, varscan2
- ATAD2B | c.2099_2102del p.H700Lfs*12 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | called by mutect2, pindel, varscan2
- CDR2L | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2
- PPL | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PPP2R5D | c.1380-1G>C p.X460_splice | Splice Site (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- SF3B1 | c.1985A>G p.H662R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA7 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR2 | c.4083G>A p.E1361= | Silent (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.540G>A p.A180= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs765799407, COSV60261877, COSV60262342; called by muse, mutect2, varscan2
- TRIM29 | c.1185C>A p.T395= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV100531627; called by muse, mutect2, varscan2
